CCDI case PBBTYK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/600bf4ee-33fa-44d3-9432-9bbf2297e839

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,871 days).

Biospecimens (3 samples)
- Sample 0DHBCS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHBD3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHBD4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
